Somatic mutation profile of tumor specimen TCGA-EB-A6R0-01A (aliquot TCGA-EB-A6R0-01A-12D-A32N-08) from TCGA case TCGA-EB-A6R0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 58.5 years (21,367 days).
Specimen TCGA-EB-A6R0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cde3c357-75fe-4f83-a1e8-a55c0dad563d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A6R0-10B (Blood Derived Normal), aliquot TCGA-EB-A6R0-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/068ba989-5700-4590-b6f8-40afb81204f9

The open-access MAF lists 449 somatic variants for this specimen: 302 protein-altering or splice-affecting, 138 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 269, Silent 138, Nonsense Mutation 16, Splice Site 6, Splice Region 6, RNA 5, Intron 3, Frame Shift Ins 2, Frame Shift Del 2, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GDF5 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 148/467 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121909350, CM085446, COSV65500464; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SHOX | c.544+1G>A p.X182_splice | Splice Site (SNP) | VAF 86/190 reads (45%) | catalogued as rs1057518701, COSV100478746; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.2251C>T p.R751* | Nonsense Mutation (SNP) | VAF 47/135 reads (35%) | catalogued as rs45517222, CM991208, COSV54756152; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ACSS1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100053351; called by muse, mutect2, varscan2
- ACSS3 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs146115032, COSV54101686; called by muse, mutect2, varscan2
- ADCK1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 116/246 reads (47%) | catalogued as COSV99450858; called by muse, mutect2, varscan2
- ADH1C | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs774092660, COSV72463676; called by muse, mutect2, varscan2
- ADRM1 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99437908; called by muse, mutect2, varscan2
- AGTR2 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100903528; called by muse, mutect2, varscan2
- AGXT2 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV99183699; called by muse, mutect2, varscan2
- AKAP14 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as rs765490964, COSV57629149; called by muse, mutect2, varscan2
- ANKRD49 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.76); catalogued as COSV100119433; called by muse, mutect2, varscan2
- ANKRD50 | c.2885C>T p.A962V | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.306); catalogued as COSV101538879; called by muse, mutect2, varscan2
- ANP32D | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 99/256 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99874225; called by muse, mutect2, varscan2
- APLP1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 87/204 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV99697468; called by muse, mutect2, varscan2
- APOL4 | c.692C>T p.S231F (on ENST00000352371 / NM_145660.2; = p.S228F on NM_030643.4) | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100274038; called by muse, mutect2, varscan2
- ARHGAP4 | c.498G>T p.T166= | Splice Region (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100603790, COSV63130724; called by muse, mutect2
- ARHGAP6 | c.2176+4A>G | Splice Region (SNP) | VAF 210/509 reads (41%) | catalogued as COSV100272229, COSV100272999; called by muse, mutect2, varscan2
- ARHGEF10L | c.2119C>T p.H707Y | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV99391906; called by muse, mutect2, varscan2
- ARHGEF12 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV63102858, COSV63107870; called by muse, mutect2, varscan2
- ARHGEF6 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV99166344, COSV99166345; called by muse, mutect2, varscan2
- ARID1B | c.3073C>T p.P1025S | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV99266917; called by muse, mutect2, varscan2
- ASPM | c.5971A>G p.K1991E | Missense Mutation (SNP) | VAF 118/255 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.879); catalogued as COSV99659448; called by muse, mutect2, varscan2
- ATF7IP | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV99661161; called by muse, mutect2, varscan2
- ATP10D | c.2560T>A p.Y854N | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99905109; called by muse, mutect2, varscan2
- BAIAP2L1 | c.343A>G p.M115V | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs750053930, COSV99133625; called by muse, mutect2, varscan2
- BAZ2A | c.4012C>T p.P1338S | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1215463787, COSV99464642; called by muse, mutect2, varscan2
- BCAN | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs755206465, COSV100227839; called by muse, mutect2, varscan2
- BICD1 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.885); catalogued as rs774882871, COSV99861940; called by muse, mutect2, varscan2
- BICD2 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.887); catalogued as rs766539334, COSV63548502; called by muse, mutect2, varscan2
- BMP1 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV100109010; called by muse, mutect2, varscan2
- BMPER | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV99778820, COSV99780010; called by muse, mutect2, varscan2
- BNIP5 | c.551T>A p.L184* | Nonsense Mutation (SNP) | VAF 51/122 reads (42%) | catalogued as COSV101465105; called by muse, mutect2, varscan2
- BRCA2 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV101203888, COSV66458059; called by muse, mutect2, varscan2
- BRWD1 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100312727; called by muse, mutect2, varscan2
- C6orf58 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV100314669; called by muse, mutect2, varscan2
- CACNA2D1 | c.1724G>A p.R575Q (on ENST00000356253 / NM_001366867.1; = p.R556Q on NM_000722.4) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62375543, COSV62391258; called by muse, mutect2, varscan2
- CADPS2 | c.2762G>A p.G921E | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100460637; called by muse, mutect2, varscan2
- CALCR | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as rs972946; called by muse, mutect2, varscan2
- CALN1 | c.220G>A p.E74K (on ENST00000329008 / NM_001017440.3; = p.E116K on NM_031468.4) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs1210215066, COSV100204106, COSV100204679; called by muse, mutect2, varscan2
- CAMK4 | c.828+1G>A p.X276_splice | Splice Site (SNP) | VAF 49/130 reads (38%) | catalogued as COSV99998233; called by muse, mutect2, varscan2
- CAMKV | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99615047; called by muse, mutect2, varscan2
- CAPN7 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.316); catalogued as COSV99512532; called by muse, mutect2, varscan2
- CATSPERD | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV101062353; called by muse, varscan2
- CATSPERD | c.829C>G p.R277G | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.262); catalogued as COSV101062356; called by muse, varscan2
- CCDC157 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs368004973, COSV100199623; called by muse, varscan2
- CCDC85A | c.1196A>G p.E399G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV101339363; called by muse, mutect2, varscan2
- CCR2 | c.239A>T p.Y80F | Missense Mutation (SNP) | VAF 126/317 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV99431957; called by muse, mutect2, varscan2
- CD22 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as rs746572402, COSV99322805; called by muse, mutect2, varscan2
- CD22 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV99322807; called by muse, mutect2, varscan2
- CD300C | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.862); catalogued as COSV100423168; called by muse, mutect2, varscan2
- CEACAM21 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV99494305; called by muse, mutect2, varscan2
- CEP128 | c.2942A>T p.D981V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99823581; called by muse, mutect2, varscan2
- CES3 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.055); catalogued as COSV100309787; called by muse, mutect2, varscan2
- CHD9 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); catalogued as COSV101271873; called by muse, mutect2, varscan2
- CMKLR1 | c.275T>A p.L92H (on ENST00000312143 / NM_001142344.2; = p.L90H on NM_004072.3) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379185; called by muse, mutect2, varscan2
- CMTM8 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 50/134 reads (37%) | catalogued as COSV100282353; called by muse, mutect2, varscan2
- COL20A1 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1472653166, COSV100489871; called by muse, mutect2, varscan2
- COL4A4 | c.3787C>T p.Q1263* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV61632295; called by muse, mutect2, varscan2
- COL4A6 | c.3344G>A p.G1115E | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563274; called by muse, mutect2, varscan2
- COL5A3 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99318187; called by muse, mutect2, varscan2
- COL7A1 | c.4837G>A p.G1613R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60394408; called by muse, mutect2, varscan2
- COQ8A | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100825548; called by muse, mutect2, varscan2
- CR1 | c.3817C>T p.P1273S | Missense Mutation (SNP) | VAF 216/510 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100887375; called by muse, mutect2, varscan2
- DAPP1 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99596567; called by muse, mutect2, varscan2
- DCANP1 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.338); catalogued as COSV72345809; called by muse, mutect2, varscan2
- DGKK | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV101052873; called by muse, mutect2, varscan2
- DGKZ | c.1364T>G p.F455C (on ENST00000454345 / NM_001105540.2; = p.F267C on NM_003646.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV100551021; called by muse, mutect2, varscan2
- DHX30 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 145/342 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1431016354, COSV100819901; called by muse, mutect2, varscan2
- DIP2A | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868761520, COSV59472702; called by muse, mutect2, varscan2
- DNAH1 | c.5428C>T p.P1810S | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776970930, COSV70227861; called by muse, mutect2, varscan2
- DNAH2 | c.8294G>A p.G2765D | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305529987, COSV66717375; called by muse, mutect2, varscan2
- DRC7 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100395352; called by muse, mutect2, varscan2
- DSC1 | c.1464A>C p.Q488H | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV99937139; called by muse, mutect2, varscan2
- EIPR1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66131099; called by muse, mutect2, varscan2
- ELN | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs144757453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELN | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99332204; called by muse, mutect2, varscan2
- EPHX3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99691445; called by muse, mutect2, varscan2
- EXOC3L4 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV101197550; called by muse, mutect2
- EXOC3L4 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV101197551; called by muse, mutect2
- FAAP100 | c.2515-1G>A p.X839_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100585188; called by muse, mutect2, varscan2
- FAM47C | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.071); catalogued as COSV100792261, COSV63726133; called by muse, mutect2, varscan2
- FAT3 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99961578; called by muse, varscan2
- FAT3 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99961585; called by muse, varscan2
- FBXO28 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV64800618; called by muse, mutect2, varscan2
- FBXO40 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.234); catalogued as rs763515142, COSV100572929; called by muse, mutect2, varscan2
- FBXW10 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.67); catalogued as COSV100111196; called by muse, mutect2, varscan2
- FCHSD2 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV100237836; called by muse, mutect2, varscan2
- FGF12 | c.295G>A p.E99K (on ENST00000454309 / NM_021032.5; = p.E37K on NM_004113.6) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs865909944, COSV53177161; called by muse, mutect2, varscan2
- FILIP1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 147/364 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1046337978, COSV52724428; called by muse, mutect2, varscan2
- FKBP11 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1382856154, COSV99872670; called by muse, mutect2, varscan2
- FNDC3B | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393523; called by muse, mutect2, varscan2
- FOXR2 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100189393; called by muse, mutect2, varscan2
- FRAS1 | c.9169C>T p.P3057S | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV99348003; called by muse, mutect2, varscan2
- FREM1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 131/165 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as COSV100772178; called by muse, mutect2, varscan2
- GABRA6 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV50880855, COSV99194053; called by muse, mutect2, varscan2
- GALNT15 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.845); catalogued as rs757851207, COSV60219598; called by muse, mutect2, varscan2
- GCN1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV100324615, COSV56106836; called by muse, mutect2, varscan2
- GHR | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 103/312 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs199937609, COSV50105878; called by muse, mutect2, varscan2
- GLP2R | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52321543; called by muse, mutect2, varscan2
- GLRA1 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.327); catalogued as COSV51018260, COSV51026129; called by muse, mutect2, varscan2
- GLYATL1 | c.781C>T p.P261S (on ENST00000317391 / NM_001354699.1; = p.P292S on NM_080661.4) | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55607273; called by muse, mutect2, varscan2
- GP9 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56624262; called by muse, mutect2, varscan2
- GPC1 | c.938T>A p.V313D | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99882567; called by muse, mutect2, varscan2
- GPR87 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as rs369844880; called by muse, mutect2, varscan2
- GRIN3A | c.1358G>A p.G453D | Missense Mutation (SNP) | VAF 84/134 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs373415839, COSV62452900; called by muse, mutect2, varscan2
- GRIP1 | c.3124C>T p.L1042F (on ENST00000359742 / NM_001379345.1; = p.L990F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.292); catalogued as COSV99667881; called by muse, mutect2, varscan2
- H1-8 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV100180358; called by muse, mutect2, varscan2
- H2BC13 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 124/351 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100704310; called by muse, mutect2, varscan2
- HCFC1 | c.1505C>T p.T502I | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100128365; called by muse, mutect2, varscan2
- HEPHL1 | c.3089G>A p.G1030E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59890768; called by muse, mutect2
- HERC2 | c.6064C>T p.R2022W | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs374218320; called by muse, mutect2, varscan2
- HMGCLL1 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51451651; called by muse, mutect2, varscan2
- HNRNPA1 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV99267364; called by muse, mutect2, varscan2
- ICAM2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56744517; called by muse, mutect2, varscan2
- IER2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV52848270; called by muse, mutect2, varscan2
- IGFBP6 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100037092; called by muse, mutect2, varscan2
- IGHA1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587732355; called by muse, mutect2, varscan2
- IKZF2 | c.1471G>A p.G491S | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100563161; called by muse, mutect2, varscan2
- IKZF4 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1232035727, COSV100008870; called by muse, mutect2, varscan2
- INSRR | c.3309G>T p.M1103I | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100947099; called by muse, mutect2, varscan2
- IQGAP2 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57186378; called by muse, mutect2, varscan2
- IRX4 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51474438; called by muse, mutect2, varscan2
- ITGA7 | c.2563G>A p.G855R (on ENST00000555728; = p.G811R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/310 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV99144245; called by muse, mutect2, varscan2
- ITGA7 | c.1052C>T p.P351L (on ENST00000555728; = p.P307L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99144246; called by muse, mutect2, varscan2
- ITGB4 | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV99563293; called by muse, mutect2, varscan2
- JMJD1C | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV67865961; called by muse, mutect2, varscan2
- KANK4 | c.2657G>A p.G886E | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100443083; called by muse, mutect2, varscan2
- KANK4 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.197); catalogued as COSV100586990; called by muse, mutect2, varscan2
- KHDRBS2 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs142287079, COSV55484670; called by muse, mutect2, varscan2
- KIAA1210 | c.4240G>A p.G1414S | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.035); catalogued as COSV101273903; called by muse, mutect2, varscan2
- KIF4A | c.3146A>C p.E1049A | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV100979338; called by muse, mutect2, varscan2
- KLHDC9 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 214/687 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100919641; called by muse, mutect2, varscan2
- KLRC1 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100760723; called by muse, mutect2, varscan2
- LACTB2 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 31/67 reads (46%) | catalogued as COSV52567464, COSV99399280; called by muse, mutect2, varscan2
- LAMA1 | c.6794T>C p.V2265A | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs1218706442, COSV101054907; called by muse, mutect2, varscan2
- LAMA2 | c.4037G>A p.G1346E | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70338493; called by muse, mutect2, varscan2
- LCE1C | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 109/197 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.998); catalogued as rs1484701798, COSV100908400; called by muse, mutect2, varscan2
- LCT | c.911T>G p.I304R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99928496; called by muse, mutect2, varscan2
- LGI2 | c.1279del p.R427Efs*20 | Frame Shift Del (DEL) | VAF 170/541 reads (31%) | catalogued as COSV66122387, COSV66122923; called by mutect2, pindel, varscan2
- LILRB1 | c.467G>A p.G156E (on ENST00000427581; = p.G120E on NM_006669.6) | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs763207069, COSV61120281; called by muse, mutect2, varscan2
- LRP1B | c.10060G>A p.E3354K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV101251928; called by muse, mutect2, varscan2
- LRRK1 | c.615G>A p.G205= | Splice Region (SNP) | VAF 90/201 reads (45%) | catalogued as COSV99437465; called by muse, mutect2, varscan2
- MAP2K2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99501942; called by muse, mutect2, varscan2
- MAP7D2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV101107139; called by muse, mutect2, varscan2
- MGAM | c.3814C>T p.P1272S | Missense Mutation (SNP) | VAF 207/386 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV72074101; called by muse, mutect2, varscan2
- MGMT | c.332C>T p.P111L (on ENST00000306010; = p.P80L on NM_002412.5) | Missense Mutation (SNP) | VAF 80/118 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100022305; called by muse, mutect2, varscan2
- MIA2 | c.1928T>G p.F643C | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99697253; called by muse, mutect2, varscan2
- MMAB | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs375412819; called by muse, mutect2, varscan2
- MORC1 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 21/32 reads (66%) | catalogued as COSV99224986; called by muse, mutect2, varscan2
- MORC1 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | catalogued as COSV99224987; called by muse, mutect2, varscan2
- MPDZ | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 207/256 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100060580; called by muse, mutect2, varscan2
- MSMP | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 288/332 reads (87%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100960090; called by muse, mutect2, varscan2
- MUC17 | c.10490C>T p.S3497L | Missense Mutation (SNP) | VAF 203/577 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60283081; called by muse, mutect2, varscan2
- MUC6 | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV101424394; called by muse, mutect2, varscan2
- NAGLU | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as rs750625891, COSV99863963; called by muse, mutect2, varscan2
- NARS1 | c.943T>A p.F315I | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99900443; called by muse, mutect2, varscan2
- NCBP1 | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100910281; called by muse, mutect2, varscan2
- NEMP1 | c.1013C>T p.P338L (on ENST00000300128 / NM_001130963.2; = p.P265L on NM_015257.3) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV55663071; called by muse, mutect2, varscan2
- NLRP12 | c.2507G>A p.G836E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as COSV100144968, COSV60743784; called by muse, mutect2, varscan2
- NLRP3 | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs200483614, COSV60221847; called by muse, mutect2, varscan2
- NOL4 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.717); catalogued as COSV99304930, COSV99305811; called by muse, mutect2, varscan2
- NOL4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 59/138 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.11); catalogued as COSV99304934; called by muse, mutect2, varscan2
- NOVA1 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as COSV99946372; called by muse, mutect2, varscan2
- NOVA2 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs754714738, COSV54358585; called by muse, mutect2, varscan2
- NPEPPS | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV100443392; called by muse, mutect2, varscan2
- NPHS1 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.208); catalogued as COSV62287677; called by muse, mutect2, varscan2
- NSUN5 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99392184; called by muse, mutect2, varscan2
- NTRK2 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as COSV52877925, COSV99452188; called by muse, mutect2, varscan2
- NUP210 | c.3661G>A p.D1221N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99595520; called by muse, mutect2, varscan2
- NUP93 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV57434481; called by muse, mutect2, varscan2
- NVL | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs200984793, COSV55873078; called by muse, mutect2, varscan2
- OLFM3 | c.554C>T p.T185I (on ENST00000338858 / NM_001288821.1; = p.T165I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58805141; called by muse, mutect2, varscan2
- OR13C5 | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV101053002; called by muse, mutect2, varscan2
- OR2A5 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1022358804, COSV101278662; called by muse, mutect2, varscan2
- OR4D1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs760207142, COSV52124382; called by muse, mutect2, varscan2
- OR6C70 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1457143387, COSV59245400; called by muse, mutect2, varscan2
- PABPC1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs1040934624, COSV100589309; called by muse, mutect2, varscan2
- PACRG | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100435308, COSV61323730; called by muse, mutect2, varscan2
- PAPLN | c.1990G>A p.G664R (on ENST00000554301; = p.G637R on NM_173462.4) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs911574354, COSV99388989; called by muse, mutect2, varscan2
- PCDHA10 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100247447; called by muse, mutect2, varscan2
- PCDHGB2 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV99530057; called by muse, mutect2, varscan2
- PCYT2 | c.762G>A p.E254= | Splice Region (SNP) | VAF 13/41 reads (32%) | catalogued as rs758341084, COSV100325916; called by muse, mutect2, varscan2
- PDE11A | c.112A>T p.K38* | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | catalogued as COSV100628332; called by muse, mutect2, varscan2
- PDE9A | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs771063811, COSV99370997; called by muse, mutect2, varscan2
- PGK2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100505293; called by muse, mutect2, varscan2
- PIK3R4 | c.1570G>A p.G524R | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.068); catalogued as COSV100768192; called by muse, mutect2, varscan2
- PKHD1 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61896797; called by muse, mutect2, varscan2
- PKHD1L1 | c.2494G>A p.G832R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV65749315; called by muse, mutect2, varscan2
- PKHD1L1 | c.8710G>A p.D2904N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV101005268; called by muse, mutect2, varscan2
- PLCH2 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs757780340, COSV99615482; called by muse, mutect2, varscan2
- PLP2 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100890086; called by muse, mutect2, varscan2
- PLXNA3 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1557204271, COSV100859791; called by muse, mutect2, varscan2
- POLG | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as rs1567192290, COSV99174472; called by muse, mutect2, varscan2
- PORCN | c.967C>T p.R323C (on ENST00000326194 / NM_203475.3; = p.R312C on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs782308739, COSV100400230, COSV58226074; called by muse, mutect2, varscan2
- POTEM | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs759985600, COSV101304650, COSV69152177; called by muse, mutect2, varscan2
- PPFIA3 | c.240G>A p.Q80= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100494675; called by muse, mutect2, varscan2
- PPP1R3A | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99491891, COSV99493393; called by muse, mutect2, varscan2
- PPP1R3F | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.916); catalogued as COSV99278356; called by muse, mutect2, varscan2
- PRAG1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV100421817; called by muse, mutect2, varscan2
- PRDM9 | c.2237A>T p.K746M | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99689731; called by muse, varscan2
- PRKAG2 | c.1587C>T p.V529= | Splice Region (SNP) | VAF 46/178 reads (26%) | catalogued as COSV99834776; called by muse, mutect2, varscan2
- PRKG1 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 73/112 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100907127; called by muse, mutect2, varscan2
- PRR16 | c.640C>T p.H214Y (on ENST00000407149 / NM_001300783.2; = p.H191Y on NM_016644.2) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758357154, COSV101086232, COSV65407836; called by muse, mutect2, varscan2
- PRSS21 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99135448; called by muse, mutect2, varscan2
- PTCHD3 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as COSV101438815; called by muse, mutect2, varscan2
- PTEN | c.699_700dup p.R234Hfs*23 | Frame Shift Ins (INS) | VAF 57/116 reads (49%) | catalogued as COSV64299623, COSV64301266, COSV64309605, COSV64309953; called by mutect2, pindel, varscan2
- PTPRK | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs745686352, COSV100949480; called by muse, mutect2, varscan2
- PTPRT | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 185/387 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100624988; called by muse, mutect2, varscan2
- PTPRT | c.89-1G>A p.X30_splice | Splice Site (SNP) | VAF 51/95 reads (54%) | catalogued as COSV62012457; called by muse, mutect2, varscan2
- RAPGEF6 | c.3722C>T p.S1241F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99725104; called by muse, mutect2, varscan2
- RBBP8NL | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs1379343219, COSV53351355; called by muse, mutect2, varscan2
- RBM11 | c.537T>G p.D179E | Missense Mutation (SNP) | VAF 136/422 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV101271173; called by muse, varscan2
- RBM11 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 136/432 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV101271175; called by muse, varscan2
- REC114 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.299); catalogued as rs373443142; called by muse, mutect2, varscan2
- RFX6 | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100263193, COSV60583355; called by muse, mutect2, varscan2
- RGS7 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV100464386; called by muse, mutect2, varscan2
- RNF113A | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 280/798 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759132287, COSV65097093, COSV65097158; called by muse, mutect2, varscan2
- ROBO4 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.991); catalogued as COSV100127273; called by muse, mutect2, varscan2
- RRBP1 | c.3907G>A p.D1303N (on ENST00000377813 / NM_001365613.2; = p.D870N on NM_004587.3) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV99853532; called by muse, mutect2, varscan2
- SAXO1 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757162575, COSV101000077; called by muse, mutect2, varscan2
- SCN10A | c.5567C>T p.T1856I | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.391); catalogued as COSV101479231; called by muse, mutect2, varscan2
- SERPINA11 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs756265934, COSV100593929, COSV58242575; called by muse, mutect2, varscan2
- SHROOM4 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99172986; called by muse, mutect2, varscan2
- SLC10A2 | c.353G>A p.W118* | Nonsense Mutation (SNP) | VAF 44/142 reads (31%) | catalogued as rs780391277, COSV55361877, COSV99807616; called by muse, mutect2, varscan2
- SLC12A9 | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307397; called by muse, mutect2, varscan2
- SLC22A2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100870912; called by muse, mutect2, varscan2
- SLC44A4 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs766584287, COSV99998566; called by muse, mutect2, varscan2
- SLC4A4 | c.1321C>T p.R441W (on ENST00000264485 / NM_001098484.3; = p.R397W on NM_003759.4) | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs530167253, COSV52625721; called by muse, mutect2, varscan2
- SLC6A1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs764382700, COSV55114252; called by muse, mutect2, varscan2
- SLCO1C1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317643371, COSV56869254; called by muse, mutect2, varscan2
- SMARCA4 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60791507; called by muse, mutect2, varscan2
- SNAP91 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV52118664; called by muse, mutect2, varscan2
- SNTB1 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1467761500, COSV101179706; called by muse, mutect2, varscan2
- SPATA22 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs200436007, COSV52152180; called by muse, mutect2, varscan2
- SRP68 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100325951; called by muse, mutect2, varscan2
- STAC3 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100234463; called by muse, mutect2, varscan2
- STRIP1 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as COSV100873940; called by mutect2, varscan2
- SUPT5H | c.3068T>G p.V1023G | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV100067725; called by muse, mutect2, varscan2
- SVOPL | c.1298G>A p.G433E (on ENST00000419765; = p.G281E on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185851913, COSV55993195; called by muse, mutect2, varscan2
- SYNDIG1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as COSV65238012; called by muse, mutect2, varscan2
- TAS2R60 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV60332091; called by muse, mutect2, varscan2
- TAT | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.061); catalogued as rs374271496, COSV100587491; called by muse, mutect2
- TEX15 | c.5836C>T p.P1946S (on ENST00000256246; = p.P2329S on NM_001350162.2) | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99820663; called by muse, mutect2, varscan2
- TEX15 | c.5690G>A p.W1897* (on ENST00000256246; = p.W2280* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 67/194 reads (35%) | catalogued as rs771958199, COSV99820664; called by muse, mutect2, varscan2
- TFF1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs199538523, COSV52299544, COSV99367300; called by muse, mutect2, varscan2
- THSD7B | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55654663; called by muse, varscan2
- THSD7B | c.2578C>T p.L860F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV55746178; called by muse, mutect2, varscan2
- TIMM29 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs777386752, COSV99449783; called by muse, mutect2, varscan2
- TLR5 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as rs1382633958, COSV60558133; called by muse, mutect2, varscan2
- TMEM117 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861723; called by muse, mutect2, varscan2
- TMEM117 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861727; called by muse, mutect2, varscan2
- TMEM132B | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs764219261, COSV100168432; called by muse, mutect2, varscan2
- TNFRSF11A | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99499930; called by muse, mutect2, varscan2
- TNRC6A | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100169404; called by muse, mutect2, varscan2
- TREML2 | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV101530136; called by muse, mutect2, varscan2
- TRPC5 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as COSV53298495; called by muse, mutect2, varscan2
- TRPV4 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as rs773622769, COSV99924353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTI1 | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as COSV100989561; called by muse, mutect2, varscan2
- TTLL5 | c.3508C>T p.R1170* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | catalogued as rs769845921, COSV100088936; called by muse, mutect2, varscan2
- TTN | c.56638A>T p.K18880* (on ENST00000591111; = p.K11456* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100593181; called by muse, mutect2, varscan2
- TTN | c.23474C>T p.P7825L (on ENST00000591111; = p.P6898L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | PolyPhen benign (0.003); catalogued as COSV59884618; called by muse, mutect2, varscan2
- UBL7 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100795341; called by muse, mutect2, varscan2
- UGT2B28 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158759, COSV59430976; called by muse, mutect2, varscan2
- UGT3A1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99954252; called by muse, mutect2, varscan2
- UNC13C | c.3626A>C p.Q1209P | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV99511301; called by muse, mutect2, varscan2
- USH2A | c.10684G>A p.E3562K | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as CM080611, COSV56427615; called by muse, mutect2, varscan2
- USP15 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99738469; called by muse, mutect2, varscan2
- VPS13D | c.10498G>A p.G3500R | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV99165417; called by muse, mutect2, varscan2
- WDPCP | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as rs1223959785, COSV99703830; called by muse, mutect2, varscan2
- WRAP53 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99872589; called by muse, mutect2, varscan2
- ZBTB16 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs1171843874, COSV100250883; called by muse, mutect2, varscan2
- ZBTB39 | c.1239G>A p.W413* | Nonsense Mutation (SNP) | VAF 39/93 reads (42%) | catalogued as rs752985346, COSV100267894; called by muse, mutect2, varscan2
- ZBTB40 | c.2987A>T p.H996L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100988802; called by muse, mutect2, varscan2
- ZC3H4 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as COSV99451692; called by muse, mutect2, varscan2
- ZFAT | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100914177; called by muse, mutect2, varscan2
- ZFPM2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV65875978, COSV99059178; called by muse, mutect2, varscan2
- ZIM3 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs150510557, COSV54142795; called by muse, mutect2, varscan2
- ZKSCAN5 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs746811775, COSV100460009; called by muse, mutect2, varscan2
- ZNF230 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV71273697; called by muse, mutect2, varscan2
- ZNF232 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV51503202; called by muse, mutect2, varscan2
- ZNF43 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 104/281 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); catalogued as COSV100731669; called by muse, mutect2, varscan2
- ZNF432 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.957); catalogued as rs757367664, COSV99659053; called by muse, mutect2, varscan2
- ZNF470 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57967675; called by muse, mutect2, varscan2
- ZNF540 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV100329437; called by muse, mutect2, varscan2
- ZNF560 | c.833T>C p.L278S | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV100038211; called by muse, mutect2, varscan2
- ZNF585A | c.1546C>T p.H516Y (on ENST00000292841 / NM_001288800.2; = p.H461Y on NM_152655.3) | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99492697; called by muse, mutect2, varscan2
- ZNF623 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.73); catalogued as COSV101513467, COSV71697132; called by muse, mutect2, varscan2
- ZNF711 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99340619; called by muse, mutect2, varscan2
- ZSWIM2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV99719896; called by muse, mutect2, varscan2
- ANKRD53 | c.259dup p.R87Pfs*3 | Frame Shift Ins (INS) | VAF 37/102 reads (36%) | called by mutect2, pindel, varscan2
- CEP85L | c.401_402delinsT p.G134Vfs*12 | Frame Shift Del (DEL) | VAF 42/140 reads (30%) | called by pindel, varscan2*
- EFL1 | c.856-2A>T p.X286_splice | Splice Site (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- FZD3 | c.386+2T>C p.X129_splice | Splice Site (SNP) | VAF 60/186 reads (32%) | called by mutect2, varscan2
- IGHA1 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV3-74 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 122/314 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC2 | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSU72P8 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPTE | c.625T>A p.F209I (on ENST00000618007 / NM_199261.4; = p.F191I on NM_199259.4) | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPTE | c.961G>A p.E321K (on ENST00000618007 / NM_199261.4; = p.E303K on NM_199259.4) | Missense Mutation (SNP) | VAF 90/461 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ABCC8 | c.1428C>T p.F476= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as rs867541142, COSV56854438; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM22 | c.900C>T p.A300= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV99715649; called by muse, mutect2, varscan2
- ADAMTS18 | c.1365G>A p.K455= | Silent (SNP) | VAF 46/76 reads (61%) | catalogued as COSV99271074; called by muse, mutect2, varscan2
- ADCY8 | c.1902G>A p.G634= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV53908811; called by muse, mutect2, varscan2
- ADGRL4 | c.234A>C p.T78= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100875553; called by muse, mutect2, varscan2
- AFF2 | c.2112G>A p.V704= | Silent (SNP) | VAF 11/248 reads (4%) | catalogued as COSV99661737; called by muse, mutect2
- ANK1 | c.5589C>T p.V1863= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as rs764663196, COSV55897249; called by muse, mutect2, varscan2
- ANKRD24 | c.1833C>T p.T611= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs775072240, COSV53669556; called by muse, mutect2, varscan2
- ARID5B | c.666C>T p.I222= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV99688961; called by muse, mutect2, varscan2
- ARX | c.1200C>T p.F400= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100984033; called by muse, mutect2
- BLM | c.105C>T p.F35= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100756903; called by muse, mutect2
- BMP1 | c.1173C>T p.P391= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100109013; called by muse, mutect2, varscan2
- C1orf158 | c.210G>A p.G70= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV55346601; called by muse, mutect2, varscan2
- CAPSL | c.207T>C p.N69= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV101274155; called by muse, mutect2, varscan2
- CASP14 | c.675G>A p.R225= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs773573153, COSV55666693; called by muse, mutect2, varscan2
- CD22 | c.1551C>T p.S517= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs778429110, COSV50049731; called by muse, mutect2, varscan2
- CDHR3 | c.1005G>A p.V335= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100487947; called by muse, mutect2, varscan2
- CHRDL2 | c.678C>T p.I226= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV99733523; called by muse, mutect2, varscan2
- CIITA | c.1968C>T p.A656= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV100161314; called by muse, mutect2, varscan2
- CIITA | c.1969C>T p.L657= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100161315; called by muse, mutect2, varscan2
- CLDN2 | c.211C>T p.L71= | Silent (SNP) | VAF 75/189 reads (40%) | catalogued as COSV100390051; called by muse, mutect2, varscan2
- CNGB1 | c.3582G>A p.G1194= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs754864561, COSV51898680; called by muse, mutect2, varscan2
- COL14A1 | c.1956G>A p.G652= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV99917943; called by muse, mutect2, varscan2
- COL6A6 | c.753C>T p.F251= | Silent (SNP) | VAF 60/203 reads (30%) | catalogued as COSV100649766, COSV62029220; called by muse, mutect2, varscan2
- COL9A3 | c.915G>A p.K305= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV59654033; called by muse, mutect2
- CRAMP1 | c.2439C>T p.L813= | Silent (SNP) | VAF 86/217 reads (40%) | catalogued as COSV99245580; called by muse, mutect2, varscan2
- CRB1 | c.1446C>T p.I482= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as rs150894028; called by muse, mutect2, varscan2
- CSMD3 | c.9801C>T p.F3267= (on ENST00000297405 / NM_001363185.1; = p.F3098= on NM_052900.3) | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs1189064124, COSV99823782; called by muse, mutect2, varscan2
- CUBN | c.8454C>T p.S2818= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV64710038; called by muse, mutect2, varscan2
- CYP2B6 | c.99G>A p.G33= | Silent (SNP) | VAF 175/518 reads (34%) | catalogued as rs200768609, COSV100137281; called by muse, mutect2, varscan2
- CYP3A7 | c.675C>T p.V225= | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as COSV100312536; called by muse, mutect2, varscan2
- DIP2A | c.4305C>T p.F1435= | Silent (SNP) | VAF 75/191 reads (39%) | catalogued as COSV59483916; called by muse, mutect2, varscan2
- DIPK1B | c.384G>A p.R128= | Silent (SNP) | VAF 45/60 reads (75%) | catalogued as COSV100765428; called by muse, mutect2, varscan2
- DST | c.6043T>C p.L2015= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99750702; called by muse, mutect2, varscan2
- EPB41L4A | c.1308C>T p.F436= | Silent (SNP) | VAF 81/247 reads (33%) | catalogued as COSV54866288; called by muse, mutect2, varscan2
- FAAH2 | c.1083C>T p.I361= | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as rs868368626, COSV66507895, COSV66509727; called by muse, mutect2, varscan2
- FBXL7 | c.705C>T p.S235= | Silent (SNP) | VAF 97/198 reads (49%) | catalogued as rs912399546, COSV100309016, COSV61650030; called by muse, mutect2, varscan2
- FBXL7 | c.849C>T p.F283= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV61641244; called by muse, mutect2, varscan2
- FGB | c.582C>T p.N194= | Silent (SNP) | VAF 78/169 reads (46%) | catalogued as rs780364193, COSV100122303; called by muse, mutect2, varscan2
- FPR2 | c.693G>A p.K231= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV60672061; called by muse, mutect2, varscan2
- FTMT | c.525G>A p.L175= | Silent (SNP) | VAF 84/244 reads (34%) | catalogued as COSV100360216; called by muse, mutect2, varscan2
- GRIA2 | c.1359C>T p.I453= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs752578545, COSV52383835; called by muse, mutect2, varscan2
- H3C3 | c.328C>T p.L110= | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as rs1554148705, COSV100778242, COSV100778288; called by muse, mutect2, varscan2
- HECW1 | c.291C>T p.V97= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs1368904676, COSV101222773; called by muse, mutect2, varscan2
- HSPA2 | c.1443C>T p.F481= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV99904681; called by muse, mutect2, varscan2
- IFIT3 | c.732C>T p.L244= | Silent (SNP) | VAF 34/59 reads (58%) | catalogued as COSV51078312; called by muse, mutect2, varscan2
- IGSF1 | c.3804C>T p.I1268= | Silent (SNP) | VAF 122/340 reads (36%) | catalogued as rs762731117, COSV63837265; called by muse, mutect2, varscan2
- ITGB4 | c.1728C>T p.P576= | Silent (SNP) | VAF 81/205 reads (40%) | catalogued as COSV99563289; called by muse, mutect2, varscan2
- KCNA1 | c.543C>T p.I181= | Silent (SNP) | VAF 70/161 reads (43%) | catalogued as COSV66837070; called by muse, mutect2, varscan2
- KIAA1958 | c.543C>T p.S181= | Silent (SNP) | VAF 52/73 reads (71%) | catalogued as COSV100515820; called by muse, mutect2, varscan2
- KLHL1 | c.2091C>T p.L697= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV64775120; called by muse, mutect2, varscan2
- KLK4 | c.504G>A p.V168= | Silent (SNP) | VAF 92/238 reads (39%) | catalogued as COSV100133519; called by muse, mutect2, varscan2
- KLK4 | c.393C>T p.T131= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as rs138226475; called by muse, mutect2, varscan2
- KLRG1 | c.192C>T p.S64= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as rs1002535739, COSV99868043; called by muse, mutect2, varscan2
- KRT5 | c.1749C>T p.S583= | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as COSV99357778; called by muse, mutect2, varscan2
- LCT | c.2100C>T p.I700= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV51545766; called by muse, mutect2, varscan2
- LEMD1 | c.456C>T p.F152= (on ENST00000367151; = p.S105F on NM_001001552.5) | Silent (SNP) | VAF 181/405 reads (45%) | catalogued as rs528538523, COSV65672042; called by muse, mutect2, varscan2
- LHX9 | c.423C>T p.S141= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as COSV61331956, COSV61332133; called by muse, mutect2, varscan2
- LILRA2 | c.495C>G p.R165= | Silent (SNP) | VAF 73/362 reads (20%) | catalogued as COSV52195500; called by muse, mutect2, varscan2
- LMF2 | c.2055C>T p.A685= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as rs746403681, COSV53316616, COSV99327364; called by muse, mutect2, varscan2
- LRRC41 | c.501C>T p.L167= | Silent (SNP) | VAF 57/123 reads (46%) | catalogued as COSV100586080; called by muse, mutect2, varscan2
- LRRC4B | c.1647G>A p.T549= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs1286246791, COSV65349218; called by muse, mutect2, varscan2
- LTBP3 | c.1443C>T p.F481= | Silent (SNP) | VAF 93/209 reads (44%) | catalogued as COSV57243695, COSV57245119; called by muse, mutect2, varscan2
- MAP1A | c.1857G>A p.E619= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100288036; called by muse, mutect2, varscan2
- MAS1L | c.444C>T p.F148= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV101009639; called by muse, mutect2, varscan2
- MGAM | c.3813C>T p.I1271= | Silent (SNP) | VAF 212/393 reads (54%) | catalogued as rs1488346187, COSV101527366; called by muse, mutect2, varscan2
- MRGPRD | c.874C>T p.L292= | Silent (SNP) | VAF 61/172 reads (35%) | catalogued as COSV100482923; called by muse, mutect2, varscan2
- MRPS10 | c.42C>T p.L14= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs778184353, COSV99273483; called by muse, mutect2, varscan2
- MUC17 | c.3075C>T p.P1025= | Silent (SNP) | VAF 285/719 reads (40%) | catalogued as COSV100071488, COSV60300571; called by muse, mutect2, varscan2
- MUC2 | c.1968G>A p.K656= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- MYH6 | c.5208G>A p.L1736= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as COSV100676264; called by muse, mutect2, varscan2
- MYH6 | c.2721C>T p.C907= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as rs1014932127, COSV62451512; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO18B | c.756G>A p.E252= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs1234890725, COSV100122524; called by muse, mutect2, varscan2
- MYO1B | c.3192C>T p.L1064= (on ENST00000304164; = p.L1006= on NM_012223.5) | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV100268581, COSV100268586; called by muse, mutect2, varscan2
- NCBP1 | c.2367G>A p.Q789= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV64305171; called by muse, mutect2, varscan2
- NLRC5 | c.105C>T p.F35= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV99346399; called by muse, mutect2, varscan2
- NPY5R | c.996G>A p.G332= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100642634; called by muse, mutect2, varscan2
- NR1D2 | c.879A>G p.Q293= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs893490386, COSV100437255; called by muse, mutect2, varscan2
- NUP210 | c.3660G>A p.L1220= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1230354208, COSV99595523; called by muse, mutect2, varscan2
- NYNRIN | c.3885C>T p.F1295= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as COSV101230490; called by muse, mutect2, varscan2
- OR10P1 | c.79C>T p.L27= | Silent (SNP) | VAF 84/218 reads (39%) | catalogued as COSV59007207; called by muse, mutect2, varscan2
- OR1M1 | c.498C>T p.L166= | Silent (SNP) | VAF 115/279 reads (41%) | catalogued as rs760479348, COSV70036986; called by muse, mutect2, varscan2
- OR51E1 | c.96C>T p.F32= | Silent (SNP) | VAF 76/214 reads (36%) | catalogued as COSV101211459; called by muse, mutect2, varscan2
- OR5R1 | c.474C>T p.F158= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as COSV56571718; called by muse, mutect2, varscan2
- OTOF | c.5481G>A p.R1827= (on ENST00000272371 / NM_194248.3; = p.R1060= on NM_004802.4) | Silent (SNP) | VAF 66/142 reads (46%) | catalogued as COSV55508458; called by muse, mutect2, varscan2
- P2RX3 | c.1104C>T p.I368= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs377490584, COSV54443596, COSV54444467; called by muse, mutect2, varscan2
- PASD1 | c.1689G>A p.Q563= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV100949057; called by muse, mutect2
- PCDHAC1 | c.1206C>T p.P402= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV99164966; called by muse, mutect2, varscan2
- PDZD2 | c.3720G>A p.G1240= | Silent (SNP) | VAF 66/183 reads (36%) | catalogued as rs778583893, COSV56852242, COSV56863623; called by muse, mutect2, varscan2
- PFAS | c.2998C>T p.L1000= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100118741; called by muse, mutect2, varscan2
- PGS1 | c.1092C>T p.I364= | Silent (SNP) | VAF 76/183 reads (42%) | catalogued as rs372825702, COSV53144741; called by muse, mutect2, varscan2
- PHOX2B | c.177C>T p.S59= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV56931306; called by muse, mutect2, varscan2
- PLIN4 | c.513G>A p.G171= (on ENST00000301286; = p.G186= on NM_001367868.2) | Silent (SNP) | VAF 81/206 reads (39%) | catalogued as COSV100012694; called by muse, mutect2, varscan2
- PNCK | c.1005C>T p.L335= (on ENST00000340888 / NM_001366975.1; = p.L418= on NM_001039582.3) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs12856628, COSV100562148; called by muse, mutect2, varscan2
- POLD1 | c.1161C>T p.I387= | Silent (SNP) | VAF 100/261 reads (38%) | catalogued as COSV101486748; called by muse, mutect2, varscan2
- POLG | c.996C>T p.S332= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs1183183052, COSV99174470; called by muse, mutect2, varscan2
- PRAMEF20 | c.1272C>T p.I424= | Silent (SNP) | VAF 111/465 reads (24%) | catalogued as rs1384564211; called by muse, mutect2, varscan2
- PSMG2 | c.474T>C p.L158= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV100466303; called by muse, mutect2, varscan2
- PTGDR | c.522C>T p.F174= | Silent (SNP) | VAF 74/208 reads (36%) | catalogued as rs745474971, COSV100035427, COSV60094744; called by muse, mutect2, varscan2
- RASGRF2 | c.1233C>T p.S411= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV99428473; called by muse, mutect2, varscan2
- RFC1 | c.162C>T p.F54= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100567409; called by muse, mutect2, varscan2
- RNF111 | c.267C>T p.L89= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs571810978, COSV62085150; called by muse, mutect2, varscan2
- S100A7L2 | c.9C>T p.I3= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV100906842, COSV64195125; called by muse, mutect2, varscan2
- SAGE1 | c.642C>T p.V214= | Silent (SNP) | VAF 87/202 reads (43%) | catalogued as COSV100186601; called by muse, varscan2
- SBK1 | c.549C>T p.F183= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100543384; called by muse, mutect2, varscan2
- SCAF1 | c.2292G>A p.R764= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100862038; called by muse, mutect2, varscan2
- SERPINE2 | c.672C>T p.S224= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs567794227, COSV99296326; called by muse, mutect2, varscan2
- SLC12A9 | c.1530C>T p.F510= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV99307391; called by muse, mutect2, varscan2
- SLC25A41 | c.1035C>T p.P345= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs556325152, COSV100382885; called by muse, mutect2, varscan2
- SLC2A9 | c.756C>T p.L252= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs1185796609, COSV99303818; called by muse, mutect2, varscan2
- SMCR8 | c.1113C>T p.L371= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as rs368357417; called by muse, mutect2, varscan2
- SNTA1 | c.804C>G p.V268= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV99458535; called by muse, mutect2, varscan2
- SPANXN3 | c.333G>A p.E111= | Silent (SNP) | VAF 80/215 reads (37%) | catalogued as COSV100980764; called by muse, mutect2, varscan2
- SPTB | c.741C>T p.I247= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs1430992970, COSV101071969; called by muse, mutect2, varscan2
- STARD13 | c.3084C>T p.T1028= (on ENST00000336934 / NM_001243476.3; = p.T910= on NM_052851.3) | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as rs1396799320, COSV99715427; called by muse, mutect2, varscan2
- SUCLA2 | c.120C>T p.N40= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as COSV101074706; called by muse, mutect2, varscan2
- SUSD3 | c.396G>A p.V132= | Silent (SNP) | VAF 66/100 reads (66%) | catalogued as COSV100968846; called by muse, mutect2, varscan2
- SYNE1 | c.23982C>T p.I7994= (on ENST00000367255 / NM_182961.4; = p.I7923= on NM_033071.3) | Silent (SNP) | VAF 81/210 reads (39%) | catalogued as rs746166486, COSV99552310; called by muse, mutect2, varscan2
- TANC2 | c.291C>T p.L97= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV101267189; called by muse, mutect2, varscan2
- TAS2R5 | c.54C>T p.L18= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as COSV99924751; called by muse, mutect2, varscan2
- TBX2 | c.774C>T p.T258= | Silent (SNP) | VAF 47/163 reads (29%) | catalogued as rs1455770013, COSV53601486, COSV99538584; called by muse, mutect2, varscan2
- TFF1 | c.105C>T p.P35= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99367303, COSV99367388; called by muse, mutect2, varscan2
- TICAM1 | c.177C>T p.I59= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV99940973; called by muse, mutect2, varscan2
- TMBIM6 | c.186G>A p.L62= | Silent (SNP) | VAF 89/234 reads (38%) | catalogued as rs963221035, COSV99920583; called by muse, mutect2, varscan2
- TPTE | c.906C>T p.I302= (on ENST00000618007 / NM_199261.4; = p.I284= on NM_199259.4) | Silent (SNP) | VAF 62/404 reads (15%) | called by muse, mutect2, varscan2
- UGT2B4 | c.828C>T p.F276= | Silent (SNP) | VAF 90/274 reads (33%) | catalogued as rs370514714; called by muse, mutect2, varscan2
- UGT2B7 | c.1006C>T p.L336= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as COSV100535097; called by muse, mutect2, varscan2
- UNC5D | c.333C>T p.V111= | Silent (SNP) | VAF 106/351 reads (30%) | catalogued as COSV99771882; called by muse, mutect2, varscan2
- VIPR1 | c.660C>T p.V220= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV100285481; called by muse, mutect2, varscan2
- WEE2 | c.951G>A p.K317= | Silent (SNP) | VAF 100/382 reads (26%) | catalogued as COSV66880319; called by muse, mutect2, varscan2
- YIPF3 | c.603C>T p.F201= | Silent (SNP) | VAF 94/262 reads (36%) | catalogued as COSV100396681; called by muse, mutect2, varscan2
- ZBTB16 | c.807G>A p.G269= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs911239693, COSV100250880; called by muse, mutect2, varscan2
- ZBTB21 | c.2091C>T p.P697= | Silent (SNP) | VAF 152/415 reads (37%) | catalogued as COSV100176893, COSV100177115; called by muse, mutect2, varscan2
- ZFYVE9 | c.1158C>T p.F386= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs1557474312, COSV99819309; called by muse, mutect2, varscan2
- ZNF32 | c.678C>T p.F226= | Silent (SNP) | VAF 47/73 reads (64%) | catalogued as COSV100986472; called by muse, mutect2, varscan2
- ZNF641 | c.1200C>T p.F400= | Silent (SNP) | VAF 79/200 reads (40%) | catalogued as COSV99973331; called by muse, mutect2, varscan2
- ZNF785 | c.1083C>T p.I361= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as rs751335582, COSV101235624; called by muse, mutect2, varscan2
- ZSCAN2 | c.1461C>T p.S487= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as COSV100306799; called by muse, mutect2, varscan2
- ADAM19 | chr5:157480999 G>A | 3'Flank (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99976023; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1425G>A | Intron (SNP) | VAF 80/182 reads (44%) | catalogued as rs1332117849, COSV100800920; called by muse, mutect2, varscan2
- AP001042.1 | n.2350C>T | RNA (SNP) | VAF 75/208 reads (36%) | called by muse, mutect2, varscan2
- DIDO1 | c.1588+27C>A | Intron (SNP) | VAF 118/232 reads (51%) | catalogued as COSV56633829, COSV99824620; called by muse, mutect2, varscan2
- HERC2P3 | n.1382C>T | RNA (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- LINC00482 | n.895C>T | RNA (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- MIR646 | n.40C>T | RNA (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2
- OR2U1P | n.797G>A | RNA (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- PTPRN2 | c.113-43020C>T | Intron (SNP) | VAF 44/182 reads (24%) | catalogued as rs1450511912, COSV101133207; called by muse, mutect2, varscan2
